Somatic mutation profile of tumor specimen TCGA-BR-8297-01A (aliquot TCGA-BR-8297-01A-12D-2340-08) from TCGA case TCGA-BR-8297, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 58.1 years (21,224 days).
Specimen TCGA-BR-8297-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87085d5d-c916-4883-acc9-e92848c5a6dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8297-10A (Blood Derived Normal), aliquot TCGA-BR-8297-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67437a93-aea6-4169-9480-6a10225677cb

The open-access MAF lists 235 somatic variants for this specimen: 176 protein-altering or splice-affecting, 49 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 49, Nonsense Mutation 7, Intron 6, Frame Shift Ins 3, RNA 3, Splice Site 2, Frame Shift Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LCE1A | c.83A>C p.K28T | Missense Mutation (SNP) | VAF 13/232 reads (6%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58726434, COSV58726966, COSV58727394; called by muse, mutect2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 36/333 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 45/161 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A2M | c.3113A>C p.N1038T | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59388240; called by muse, mutect2
- AAR2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); catalogued as rs781465836, COSV57923692, COSV57923989; called by muse, mutect2
- ABCA12 | c.7144T>G p.F2382V (on ENST00000272895 / NM_173076.3; = p.F2064V on NM_015657.3) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV55962838; called by muse, mutect2
- ABCB1 | c.405T>G p.F135L | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV55953772; called by muse, mutect2
- ACSL6 | c.548C>T p.P183L (on ENST00000379240; = p.P208L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV57299083, COSV57299974; called by muse, mutect2, varscan2
- ACTRT1 | c.881T>G p.L294R | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64419585; called by muse, mutect2
- ADAMTS5 | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.826); catalogued as COSV99537787; called by muse, mutect2
- ADGRL2 | c.2848A>G p.K950E (on ENST00000370717 / NM_001366005.1; = p.K937E on NM_012302.4) | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as rs1214612771, COSV54672325; called by muse, mutect2
- ANKRD30A | c.547A>G p.R183G (on ENST00000611781; = p.R127G on NM_052997.2) | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as COSV64612724; called by muse, mutect2
- APAF1 | c.2155G>A p.G719R (on ENST00000551964 / NM_181861.2; = p.G708R on NM_001160.3) | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV59665052; called by muse, mutect2
- APLP1 | c.1096T>C p.S366P | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55703488; called by muse, mutect2, varscan2
- APOB | c.5531C>T p.S1844F | Missense Mutation (SNP) | VAF 57/378 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51939489; called by muse, mutect2, varscan2
- ATP10D | c.2370A>C p.Q790H | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV56712536; called by muse, mutect2
- BCAS3 | c.424T>G p.F142V | Missense Mutation (SNP) | VAF 77/726 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV66405096; called by muse, mutect2, varscan2
- BMP1 | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 89/394 reads (23%) | catalogued as rs898240891, COSV60531680; called by muse, mutect2, varscan2
- BMPER | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV51821832; called by muse, mutect2
- BRINP1 | c.13T>G p.F5V | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.018); catalogued as COSV56303050; called by muse, mutect2
- CARD11 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs1171346123, COSV67798384; called by muse, mutect2
- CARD9 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59996451; called by muse, mutect2, varscan2
- CC2D2B | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 52/638 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs374439752; called by muse, mutect2
- CCDC172 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769448112, COSV60936457, COSV60936505, COSV60938265; called by muse, mutect2
- CCDC60 | c.797G>C p.S266T | Missense Mutation (SNP) | VAF 34/511 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV59545345; called by muse, mutect2
- CD38 | c.641A>T p.K214I | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV56891075; called by muse, mutect2
- CELSR1 | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV53092486; called by muse, mutect2
- CFAP61 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV55633375; called by muse, mutect2
- CFH | c.1636A>C p.S546R | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.549); catalogued as COSV66409598; called by muse, mutect2
- CHD9 | c.1547dup p.V517Gfs*11 | Frame Shift Ins (INS) | VAF 21/130 reads (16%) | catalogued as rs772443637; called by mutect2, pindel, varscan2
- CHRM2 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.828); catalogued as COSV57775026; called by muse, mutect2, varscan2
- CKAP5 | c.4952T>G p.L1651R (on ENST00000529230 / NM_001008938.4; = p.L1591R on NM_014756.3) | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV56369153; called by muse, mutect2, varscan2
- CLEC12A | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100429765, COSV58561507; called by muse, mutect2, varscan2
- CMYA5 | c.9822A>C p.Q3274H | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV71406589; called by muse, mutect2, varscan2
- CNRIP1 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV55148884; called by muse, mutect2
- CNTN3 | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55174447, COSV99723271; called by muse, mutect2
- CNTNAP2 | c.531A>C p.E177D | Missense Mutation (SNP) | VAF 45/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62197769; called by muse, mutect2, varscan2
- CNTNAP2 | c.1472A>C p.K491T | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV62151535; called by muse, mutect2, varscan2
- CNTNAP5 | c.1211T>C p.L404P | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70472881, COSV70490958; called by muse, mutect2, varscan2
- CPXM2 | c.2047A>G p.N683D | Missense Mutation (SNP) | VAF 30/638 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53863984; called by muse, mutect2
- CRACD | c.2877A>T p.Q959H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV51723504; called by muse, mutect2
- CRISPLD1 | c.1405A>G p.R469G | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51549324; called by muse, mutect2
- DCLK1 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55192174; called by muse, mutect2, varscan2
- DCT | c.555dup p.V186Cfs*9 | Frame Shift Ins (INS) | VAF 42/300 reads (14%) | catalogued as rs762895555; called by mutect2, varscan2
- DIO2 | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV70445336; called by muse, mutect2
- DISC1 | c.1804T>C p.W602R | Missense Mutation (SNP) | VAF 17/271 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54409760; called by muse, mutect2
- DMXL1 | c.2974T>G p.C992G | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60714038; called by muse, mutect2
- DNAH11 | c.7218T>G p.F2406L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs775857825, COSV60960932; called by muse, mutect2, varscan2
- DOCK2 | c.4340C>G p.P1447R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99913119; called by muse, mutect2
- DST | c.4729C>T p.L1577F | Missense Mutation (SNP) | VAF 67/565 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as COSV99757278; called by muse, mutect2, varscan2
- DYSF | c.617C>A p.A206E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.153); catalogued as COSV50451196; called by muse, mutect2, varscan2
- EDRF1 | c.3184G>T p.A1062S (on ENST00000356792 / NM_001202438.2; = p.A1028S on NM_015608.2) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61764458; called by muse, mutect2, varscan2
- EGLN1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs769647331, CM147078, COSV64149626; called by muse, mutect2, varscan2
- EHBP1 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.8); catalogued as COSV50423015; called by muse, mutect2
- FAF2 | c.344+2T>G p.X115_splice | Splice Site (SNP) | VAF 19/110 reads (17%) | catalogued as COSV56131423; called by muse, mutect2
- FAT4 | c.10554A>C p.E3518D | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV58687060, COSV58690636; called by muse, mutect2
- FAT4 | c.13332G>T p.E4444D | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.961); catalogued as COSV58690648; called by muse, mutect2, varscan2
- FGF12 | c.664C>T p.R222C (on ENST00000454309 / NM_021032.5; = p.R160C on NM_004113.6) | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1427870966, COSV53170192; called by muse, mutect2
- FMN2 | c.4872A>C p.Q1624H | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV60422561, COSV60449037; called by muse, mutect2
- GALNT17 | c.1525T>G p.F509V | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100356490, COSV61153988; called by muse, mutect2
- GLI3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs778060205, COSV67889805; called by muse, mutect2
- GPR85 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 23/200 reads (12%) | catalogued as COSV51782558; called by muse, mutect2, varscan2
- GPRASP2 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV59991645; called by muse, mutect2, varscan2
- GRIN3B | c.1804G>A p.G602S | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556153075, COSV52261014; called by muse, mutect2, varscan2
- GRM3 | c.1954T>G p.F652V | Missense Mutation (SNP) | VAF 34/470 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV64473557; called by muse, mutect2
- GRM7 | c.2092A>G p.S698G | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63148038; called by muse, mutect2
- GSPT2 | c.547A>G p.K183E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61214518; called by muse, mutect2
- HCRTR1 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV65485746, COSV65486480; called by muse, mutect2
- HGF | c.1070C>A p.P357Q | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55951364; called by muse, mutect2
- HSD3B1 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52491109; called by muse, mutect2
- HTR1F | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100138195, COSV60389317; called by muse, mutect2, varscan2
- IFNB1 | c.477C>G p.Y159* | Nonsense Mutation (SNP) | VAF 32/432 reads (7%) | catalogued as COSV66525496; called by muse, mutect2
- JUNB | c.1000A>T p.N334Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV56878078; called by muse, mutect2, varscan2
- KAT6A | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 61/938 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770521888, COSV55907293; called by muse, mutect2
- KCNH5 | c.85T>G p.L29V | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.162); catalogued as COSV59763416; called by muse, mutect2, varscan2
- KCNH8 | c.2329A>C p.T777P | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60466821; called by muse, mutect2
- KLHL12 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1157462026, COSV66127535; called by muse, mutect2
- KLRG1 | c.523A>G p.S175G | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56942005, COSV56943725; called by muse, mutect2
- KRT84 | c.1185T>G p.I395M | Missense Mutation (SNP) | VAF 49/603 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs746202681, COSV57772093; called by muse, mutect2
- KRTAP9-3 | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.06); catalogued as COSV100893199; called by muse, mutect2
- LENG9 | c.1336A>T p.S446C | Missense Mutation (SNP) | VAF 87/250 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as COSV56618694; called by muse, mutect2, varscan2
- LRP1B | c.3461A>G p.E1154G | Missense Mutation (SNP) | VAF 23/366 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as COSV67233867; called by muse, mutect2
- LRRC4C | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV53427082, COSV99536568; called by muse, mutect2
- LRRK2 | c.1601A>C p.K534T | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54156735; called by muse, mutect2
- MAGEE2 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV64897905; called by muse, mutect2, varscan2
- MDGA2 | c.1969T>C p.F657L (on ENST00000399232 / NM_001113498.2; = p.F359L on NM_182830.4) | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV62097322; called by muse, mutect2, varscan2
- MED24 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as rs946309583, COSV62419207; called by muse, mutect2
- MS4A2 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV54012753; called by muse, mutect2
- MUC5B | c.12199T>C p.S4067P | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV71592938; called by muse, mutect2, varscan2
- MYH10 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52603528; called by muse, mutect2, varscan2
- MYRIP | c.285C>G p.Y95* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as COSV56871780; called by muse, mutect2
- NCKAP5 | c.193A>C p.S65R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV58450686; called by muse, mutect2
- NEGR1 | c.548A>C p.E183A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV60850582; called by muse, mutect2
- NFIA | c.865G>C p.G289R | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV64539082; called by muse, mutect2
- NPY2R | c.541A>C p.S181R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.926); catalogued as COSV61528588; called by muse, mutect2
- OBSCN | c.3925G>A p.A1309T | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs768014393, COSV52736916, COSV52784717; called by muse, mutect2
- OR10K1 | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV56872442; called by muse, mutect2
- OR10K2 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as COSV59221516; called by muse, mutect2
- OR10K2 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 50/504 reads (10%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.556); catalogued as COSV59221524; called by muse, mutect2
- OR2L2 | c.9T>G p.N3K | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63550757; called by muse, mutect2
- OTUD4 | c.1362A>C p.E454D (on ENST00000447906 / NM_001366057.1; = p.E389D on NM_001102653.1) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV71381957; called by muse, mutect2
- PAQR9 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61418428; called by muse, mutect2, varscan2
- PARP11 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57395529, COSV99959344; called by muse, mutect2
- PCDH15 | c.5634A>C p.E1878D | Missense Mutation (SNP) | VAF 32/670 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV57330048; called by muse, mutect2
- PCDHGA2 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV53966787; called by muse, mutect2
- PCLO | c.5076T>G p.Y1692* | Nonsense Mutation (SNP) | VAF 24/157 reads (15%) | catalogued as COSV61641653; called by muse, mutect2, varscan2
- PITPNM1 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54160940; called by muse, mutect2
- PLCB1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV62056013; called by muse, mutect2
- PQBP1 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54430801; called by muse, mutect2
- PTBP3 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.079); catalogued as COSV57584002; called by muse, mutect2
- PTCHD4 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); catalogued as rs777076189, COSV59781311; called by muse, mutect2, varscan2
- PTPRZ1 | c.2918A>C p.K973T | Missense Mutation (SNP) | VAF 19/331 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV66429333; called by muse, mutect2
- PYGL | c.856-2A>C p.X286_splice | Splice Site (SNP) | VAF 29/228 reads (13%) | catalogued as COSV53586538; called by muse, mutect2, varscan2
- PYHIN1 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV63722804; called by muse, mutect2
- QKI | c.902T>G p.L301R | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51696086; called by muse, mutect2
- RELN | c.4592T>G p.L1531R | Missense Mutation (SNP) | VAF 22/228 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59009246; called by muse, mutect2
- RIMS2 | c.4676del p.F1559Sfs*6 (on ENST00000666250 / NM_001348490.2; = p.F1130Sfs*6 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 60/579 reads (10%) | catalogued as COSV51678593, COSV99154996; called by mutect2, pindel, varscan2
- ROBO1 | c.2764C>T p.R922C | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767615237, COSV71392654; called by muse, mutect2
- RUBCN | c.2651G>T p.C884F | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56367705; called by muse, mutect2
- RXFP3 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs766386923, COSV57505243; called by muse, mutect2, varscan2
- SACS | c.10160T>G p.L3387R | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66541577; called by muse, mutect2
- SALL3 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73306133; called by muse, mutect2
- SCRIB | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as rs374302020, COSV57588484; called by muse, mutect2
- SDE2 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs374097572; called by muse, mutect2, varscan2
- SERPINA7 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV59664815; called by muse, mutect2
- SETBP1 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56318335; called by muse, mutect2, varscan2
- SFRP4 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52260298; called by muse, mutect2
- SLC10A2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs775125105, COSV55359783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC38A4 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 30/481 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56968403; called by muse, mutect2
- SLC5A11 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 53/420 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.243); catalogued as rs61744722, COSV61741471; called by muse, mutect2, varscan2
- SLC5A4 | c.1131A>G p.G377= | Splice Region (SNP) | VAF 15/138 reads (11%) | catalogued as COSV56671203; called by muse, mutect2, varscan2
- SNTG1 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.221); catalogued as COSV52450146; called by muse, mutect2
- SOHLH2 | c.711T>A p.D237E | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65902464; called by muse, mutect2
- SORCS1 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV53874770; called by muse, mutect2
- SPATS2L | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62349172, COSV62352934; called by muse, mutect2, varscan2
- SPRED3 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100612795, COSV58312955; called by muse, mutect2, varscan2
- SPTA1 | c.6953A>G p.K2318R | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63754869; called by muse, mutect2
- SPTA1 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372067263, COSV63749356; called by muse, mutect2, varscan2
- SPTA1 | c.517T>C p.W173R | Missense Mutation (SNP) | VAF 66/846 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63754876; called by muse, mutect2
- SUGCT | c.1175A>C p.K392T (on ENST00000335693 / NM_001193313.2; = p.K418T on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/506 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV59334554; called by muse, mutect2
- SZT2 | c.2738A>C p.Q913P | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65170819; called by muse, mutect2, varscan2
- TAF1L | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 168/525 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.487); catalogued as rs750016255, COSV54263428; called by muse, mutect2, varscan2
- TAF4 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 68/302 reads (23%) | catalogued as COSV53338622; called by muse, mutect2, varscan2
- TAS2R16 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50797370; called by muse, mutect2
- TBC1D17 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 7/74 reads (9%) | catalogued as COSV55579190; called by muse, mutect2
- TFPI2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.162); catalogued as COSV55990911; called by muse, mutect2
- THSD4 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 39/563 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55973073; called by muse, mutect2
- TLL1 | c.1021A>G p.R341G | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV50292687; called by muse, mutect2
- TLR4 | c.1492T>G p.L498V (on ENST00000355622 / NM_138554.5; = p.L458V on NM_003266.4) | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2, varscan2
- TMPRSS11F | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.418); catalogued as COSV62467117; called by muse, mutect2
- TMPRSS15 | c.1624T>C p.F542L | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV53034112, COSV53041704; called by muse, mutect2
- TNS2 | c.4105G>A p.V1369M (on ENST00000314250 / NM_170754.4; = p.V1379M on NM_015319.2) | Missense Mutation (SNP) | VAF 34/533 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373363715; called by muse, mutect2
- TRPS1 | c.286A>C p.N96H (on ENST00000220888 / NM_001330599.2; = p.N109H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV55246335; called by muse, mutect2
- TSNAXIP1 | c.1974C>A p.S658R | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.181); catalogued as COSV54650322; called by muse, mutect2, varscan2
- TTBK2 | c.2404A>G p.I802V | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV51164352; called by muse, mutect2
- TTN | c.48929C>T p.P16310L (on ENST00000591111; = p.P8886L on NM_003319.4) | Missense Mutation (SNP) | VAF 35/180 reads (19%) | PolyPhen possibly damaging (0.844); catalogued as COSV100630718, COSV60128703; called by muse, mutect2, varscan2
- TUBB2B | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 25/498 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV99455489; called by muse, mutect2
- UBE2J2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 67/791 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs755105629, COSV59571961; called by muse, mutect2
- UBE3C | c.3203G>A p.S1068N | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV61953893; called by muse, mutect2
- UBR4 | c.9478C>G p.L3160V | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64391810; called by muse, mutect2
- UBR5 | c.1850G>A p.C617Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55290297; called by muse, mutect2
- UNG | c.674C>G p.S225C (on ENST00000242576 / NM_080911.3; = p.S216C on NM_003362.4) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV54357369, COSV54357584; called by muse, mutect2
- USP29 | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54143737; called by muse, mutect2, varscan2
- XIRP2 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54708443; called by muse, mutect2
- ZDBF2 | c.1545A>C p.E515D | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV65626965, COSV65628388; called by muse, mutect2
- ZFPM2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.084); catalogued as COSV65872531; called by muse, mutect2
- ZKSCAN1 | c.901T>G p.F301V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV60874342; called by muse, mutect2
- ZNF311 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV65853164; called by muse, mutect2, varscan2
- ZNF91 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV56085977; called by muse, mutect2
- CKAP2 | c.1621G>C p.D541H (on ENST00000378037 / NM_001098525.2; = p.D540H on NM_018204.5) | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); called by muse, mutect2
- IGKV3D-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2
- KLF3 | c.589dup p.I197Nfs*2 | Frame Shift Ins (INS) | VAF 36/189 reads (19%) | called by mutect2, varscan2
- MUC5B | c.3935C>A p.T1312N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PCDHB8 | c.237T>A p.N79K | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- SPATA31A1 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 126/795 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SPATA31A1 | c.3656A>G p.E1219G | Missense Mutation (SNP) | VAF 52/780 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2
- AASS | c.2592C>T p.I864= | Silent (SNP) | VAF 83/846 reads (10%) | catalogued as COSV62790461; called by muse, mutect2, varscan2
- AIDA | c.561C>G p.P187= | Silent (SNP) | VAF 18/259 reads (7%) | catalogued as COSV60664350; called by muse, mutect2
- ANGPT1 | c.664T>C p.L222= | Silent (SNP) | VAF 16/235 reads (7%) | catalogued as COSV52444233; called by muse, mutect2
- BRD9 | c.1323C>T p.D441= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as rs1406821967, COSV60245226; called by muse, mutect2
- BRPF3 | c.2520C>T p.P840= | Silent (SNP) | VAF 21/387 reads (5%) | catalogued as COSV60208005; called by muse, mutect2
- CYRIA | c.855A>G p.K285= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV62864409, COSV62865839, COSV62867483; called by muse, mutect2
- DCLK3 | c.1291C>T p.L431= | Silent (SNP) | VAF 10/211 reads (5%) | catalogued as rs938211918, COSV101373999; called by muse, mutect2
- DCLK3 | c.1290C>T p.I430= | Silent (SNP) | VAF 10/211 reads (5%) | catalogued as COSV101374000, COSV69364276; called by muse, mutect2
- DDX50 | c.189A>G p.K63= | Silent (SNP) | VAF 63/323 reads (20%) | catalogued as rs981554594, COSV65292031; called by muse, mutect2, varscan2
- DGKI | c.3114T>C p.A1038= | Silent (SNP) | VAF 11/246 reads (4%) | catalogued as COSV55955424; called by muse, mutect2
- DOCK5 | c.1206C>T p.S402= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV52407843; called by muse, mutect2
- EBF3 | c.855C>T p.G285= (on ENST00000355311 / NM_001375392.1; = p.G276= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs149960200; called by muse, mutect2, varscan2
- FAM91A1 | c.1296A>G p.E432= | Silent (SNP) | VAF 16/386 reads (4%) | catalogued as COSV58237720; called by muse, mutect2
- FKBP8 | c.423G>A p.P141= | Silent (SNP) | VAF 45/419 reads (11%) | catalogued as rs917631081, COSV55892771; called by muse, mutect2, varscan2
- GALNT13 | c.762T>C p.T254= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as COSV101224183, COSV67224717, COSV67225652; called by muse, mutect2
- GALNT17 | c.300G>A p.P100= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as rs770531592, COSV61167193; called by muse, mutect2, varscan2
- GPC1 | c.1662G>A p.R554= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV50863963; called by muse, mutect2, varscan2
- IKZF1 | c.759G>T p.L253= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV58787308; called by muse, mutect2
- INA | c.963G>A p.A321= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV63976140; called by muse, mutect2
- JHY | c.213C>T p.P71= | Silent (SNP) | VAF 37/271 reads (14%) | catalogued as rs764183163, COSV56219921; called by muse, mutect2, varscan2
- KLHL4 | c.1107T>C p.S369= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as COSV64139442, COSV64143670; called by muse, mutect2, varscan2
- MAP2 | c.525A>C p.S175= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as COSV52294970, COSV99559000; called by muse, mutect2
- MED12 | c.6132A>T p.S2044= | Silent (SNP) | VAF 50/224 reads (22%) | catalogued as COSV61343323; called by muse, varscan2
- NAV1 | c.2535G>A p.P845= | Silent (SNP) | VAF 36/649 reads (6%) | catalogued as rs144457633; called by muse, mutect2
- NDNF | c.1107T>A p.S369= | Silent (SNP) | VAF 20/320 reads (6%) | catalogued as COSV65633811; called by muse, mutect2
- NOVA1 | c.696A>G p.K232= | Silent (SNP) | VAF 24/330 reads (7%) | catalogued as rs1437521953, COSV57479353; called by muse, mutect2
- OR10Z1 | c.750T>C p.I250= | Silent (SNP) | VAF 43/612 reads (7%) | catalogued as COSV63525209; called by muse, mutect2
- OR1E1 | c.66G>A p.E22= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV100491952; called by muse, mutect2
- OR2T4 | c.675A>C p.S225= | Silent (SNP) | VAF 26/595 reads (4%) | catalogued as COSV63544240; called by muse, mutect2
- OR52N4 | c.193T>C p.L65= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV57891474; called by muse, mutect2, varscan2
- PCDH9 | c.3309T>G p.T1103= (on ENST00000377865 / NM_203487.3; = p.T1069= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as COSV60558530; called by muse, mutect2, varscan2
- PLG | c.1785A>G p.Q595= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV57517338; called by muse, mutect2
- PREX2 | c.2349T>C p.A783= | Silent (SNP) | VAF 18/364 reads (5%) | catalogued as rs1405412237, COSV55756430, COSV55778503; called by muse, mutect2
- PRUNE2 | c.6804T>C p.D2268= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV65042766; called by muse, mutect2, varscan2
- PTCHD3 | c.30G>A p.P10= | Silent (SNP) | VAF 43/251 reads (17%) | catalogued as rs369428695; called by muse, mutect2, varscan2
- RAPH1 | c.642C>T p.S214= | Silent (SNP) | VAF 57/381 reads (15%) | catalogued as rs760714383, COSV57354377; called by muse, mutect2, varscan2
- RELN | c.2418T>C p.T806= | Silent (SNP) | VAF 33/264 reads (13%) | catalogued as rs199631495, COSV59009255; called by muse, mutect2, varscan2
- RNF17 | c.4308T>G p.T1436= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV55042377; called by muse, mutect2, varscan2
- RORB | c.1398C>T p.A466= (on ENST00000396204 / NM_001365023.1; = p.A455= on NM_006914.4) | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as COSV65336731; called by muse, mutect2
- RTL9 | c.3069T>G p.A1023= | Silent (SNP) | VAF 32/382 reads (8%) | catalogued as COSV71825755; called by muse, mutect2
- SEMA5A | c.1950T>C p.C650= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV66795862; called by muse, mutect2, varscan2
- STAT1 | c.1429C>T p.L477= | Silent (SNP) | VAF 47/343 reads (14%) | catalogued as COSV63116486; called by muse, mutect2, varscan2
- STAT6 | c.165C>T p.A55= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as COSV55671743; called by muse, mutect2, varscan2
- TAT | c.594G>T p.L198= | Silent (SNP) | VAF 13/201 reads (6%) | catalogued as COSV63533024; called by muse, mutect2
- TNFAIP1 | c.345G>A p.G115= | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as COSV56876954; called by muse, mutect2
- URI1 | c.1308A>T p.G436= | Silent (SNP) | VAF 47/209 reads (22%) | catalogued as COSV56350689; called by muse, mutect2, varscan2
- ZBTB40 | c.1878G>C p.L626= | Silent (SNP) | VAF 29/366 reads (8%) | catalogued as COSV65145615; called by muse, mutect2
- ZNF135 | c.882T>C p.G294= (on ENST00000313434 / NM_001289401.2; = p.G306= on NM_003436.4) | Silent (SNP) | VAF 12/214 reads (6%) | catalogued as COSV57882999; called by muse, mutect2
- ZNF471 | c.1110T>C p.T370= | Silent (SNP) | VAF 22/366 reads (6%) | catalogued as COSV57291786; called by muse, mutect2
- AL109984.1 | n.186+1371C>A | Intron (SNP) | VAF 22/237 reads (9%) | catalogued as COSV63752769; called by muse, mutect2
- AL136982.4 | n.573G>T | RNA (SNP) | VAF 60/910 reads (7%) | called by muse, mutect2
- CLN5 | c.*149T>G | 3'UTR (SNP) | VAF 20/208 reads (10%) | catalogued as COSV62918869; called by muse, mutect2
- CRELD1 | c.1049-348C>G | Intron (SNP) | VAF 18/242 reads (7%) | catalogued as COSV55978728, COSV99926616; called by muse, mutect2
- CTNNA2 | c.1057-79620A>T | Intron (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100561121; called by muse, mutect2
- DCHS2 | n.7374_7394del | RNA (DEL) | VAF 27/284 reads (10%) | called by mutect2, pindel
- DCHS2 | n.4943C>T | RNA (SNP) | VAF 9/172 reads (5%) | catalogued as COSV61773611; called by muse, mutect2
- NALCN | c.1765-4857T>C | Intron (SNP) | VAF 10/220 reads (5%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2
- TRPM3 | c.979+17848G>T | Intron (SNP) | VAF 26/351 reads (7%) | catalogued as COSV100677593, COSV100678120; called by muse, mutect2
- TTN | c.10360+2859A>C | Intron (SNP) | VAF 15/299 reads (5%) | catalogued as COSV60128746; called by muse, mutect2
